Somatic mutation profile of tumor specimen 0DTFRP from CCDI case PBCIZU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.5 years (4,930 days).
Specimen 0DTFRP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8dba633-2b54-4c58-9d51-ce56fb85dc29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTFRV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfc1f8b7-5b2b-4569-aa72-43ff7c92d779

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 3, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.1004C>T p.T335I (on ENST00000611781; = p.T279I on NM_052997.2) | Missense Mutation (SNP) | VAF 1037/3528 reads (29%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.969); catalogued as rs749662238; called by muse, mutect2, varscan2
- CBLL2 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 673/848 reads (79%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.488); catalogued as rs775692278; called by muse, mutect2, varscan2
- DNAJC13 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 520/1324 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs780669417; called by muse, mutect2
- KIFC3 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 32/1086 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980456107, COSV65552264; called by muse, mutect2
- C9orf78 | c.20T>C p.I7T | Missense Mutation (SNP) | VAF 320/698 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDI2 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 634/1537 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- NFYC | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 579/1543 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R14C | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 267/692 reads (39%) | called by muse, mutect2, varscan2
- SEPSECS | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 41/1394 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- SLCO4A1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 741/1529 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 60/1294 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CARNS1 | c.1596G>A p.L532= | Silent (SNP) | VAF 429/1501 reads (29%) | catalogued as rs1412533866; called by mutect2, varscan2
- CARNS1 | c.1896G>C p.T632= | Silent (SNP) | VAF 329/1139 reads (29%) | catalogued as COSV57052485; called by muse, mutect2, varscan2
- SACS | c.6087T>G p.L2029= | Silent (SNP) | VAF 845/1890 reads (45%) | called by muse, mutect2, varscan2
- TJP2 | c.870G>A p.P290= | Silent (SNP) | VAF 92/1060 reads (9%) | called by muse, mutect2
- TMEM200C | c.1077C>T p.P359= | Silent (SNP) | VAF 273/800 reads (34%) | called by muse, mutect2, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 13/278 reads (5%) | called by muse, mutect2
- DAPK1 | c.2001+55T>G | Intron (SNP) | VAF 375/789 reads (48%) | called by muse, mutect2, varscan2
- DENND11 | c.*39G>C | 3'UTR (SNP) | VAF 60/1112 reads (5%) | called by muse, mutect2
- LLGL2 | c.2997-37C>T | Intron (SNP) | VAF 313/953 reads (33%) | catalogued as rs1336876640; called by muse, mutect2, varscan2
- MGAT1 | c.-47G>T | 5'UTR (SNP) | VAF 97/210 reads (46%) | called by muse, mutect2, varscan2
- OIT3 | chr10:72893711 del A | 5'Flank (DEL) | VAF 64/130 reads (49%) | catalogued as rs1161219246, COSV61825112; called by mutect2, varscan2
